Somatic mutation profile of tumor specimen ALCH-B2EI-TTP1-A (aliquot ALCH-B2EI-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2EI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.4 years (19,145 days).
Specimen ALCH-B2EI-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 303ab8f2-3de9-4491-92dc-935c77f1de1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2EI-NB1-A (Blood Derived Normal), aliquot ALCH-B2EI-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8966b064-7eaa-4fd3-a9d0-d740ab7defcb

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs780689830, COSV58141313; called by muse, mutect2, varscan2
- HSD11B1L | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs1443792570; called by muse, mutect2, varscan2
- HSPG2 | c.8888G>A p.G2963D | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99057930; called by muse, mutect2
- IGF2R | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 38/538 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201251256, COSV100808065; called by muse, mutect2
- NCAPD2 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 34/510 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1442483081; called by muse, mutect2
- NDST4 | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 10/132 reads (8%) | catalogued as COSV52137800; called by muse, mutect2
- TAF1 | c.2466C>G p.I822M (on ENST00000373790 / NM_138923.4; = p.I843M on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM239 | c.362G>A p.C121Y (on ENST00000361033 / NM_001318207.1; = p.C78Y on NM_001167670.3) | Missense Mutation (SNP) | VAF 25/375 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, mutect2
- ITGA4 | c.1794A>T p.P598= | Silent (SNP) | VAF 17/205 reads (8%) | called by muse, mutect2
- TYMS | c.516T>C p.P172= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as rs1297054326; called by muse, mutect2
- DENND5B | c.128-4617A>G | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
